Surgical pathology report (de-identified scan), TCGA case TCGA-NF-A4X2, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-NF-A4X2-01A (Primary Tumor).

[page 1 of 2]
ICD-6-3

Carcinoma, mixed Mullerian
Tumor, malignant 8950/3
Site: Path Endometrium C54.1
C4CF uterus NOS C55.9
9/2/19/13

SLIDE DISPOSITION:

DIAGNOSIS:

A. Uterus, left and right fallopian tubes and ovaries, hysterectomy and bilateral salpingo-oophorectomy: Malignant mixed Mullerian tumor with heterologous differentiation (60% glandular, 40% stromal differentiation) is identified forming a mass, 7.5 x 7.0 x 2.0 cm, circumferentially involving the uterine cavity. The tumor invades 2.0 cm into the myometrium (total wall thickness 2.4 cm). The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. Bilateral fallopian tubes display severe epithelial atypia. The ovaries are unremarkable. Seen in consultation with Dr.

B. Lymph nodes, right pelvic, excision: Multiple (19) lymph nodes are negative for tumor.

C. Lymph nodes, left pelvic, excision: Multiple (15) lymph nodes are negative for tumor.

D. Lymph nodes, left para-aortic, excision: Multiple (14) lymph nodes are negative for tumor.

E. Lymph nodes, right para-aortic, excision: Multiple (2) lymph nodes are negative for tumor.

with available surgical material [AJCC pT1bN0] (7th edition,)

AMENDMENTS: (Previous Signout Date:

Revision Description: Need to add frozen section diagnosis to part A.

...Original Frozen Sect-Intraop...

A. Uterus, left and right fallopian tubes and ovaries, hysterectomy and bilateral salpingo-oophorectomy: Malignant mixed Mullerian tumor with heterologous differentiation invading into the outer half of myometrium and confined to the uterus. Endocervix shows focal atypical glands suspicious for adenocarcinoma in situ. HOLDOVER to evaluate on permanent sections.

B. Lymph nodes, right pelvic, excision: Multiple (19) lymph nodes are negative for tumor.

C. Lymph nodes, left pelvic, excision: Multiple (15) lymph nodes are negative for tumor.

Frozen section histologic interpretation performed by:

D. Lymph nodes, left para-aortic, excision: Multiple (14) lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

E. Lymph nodes, right para-aortic, excision: Multiple (2) lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

Frozen section histologic interpretation performed by:

PRELIMINARY FROZEN SECTION CONSULTATION:

A. Uterus, left and right fallopian tubes and ovaries, hysterectomy

[page 2 of 2]
and bilateral salpingo-oophorectomy: Malignant mixed Mullerian tumor with heterologous differentiation invading into the outer half of myometrium and confined to the uterus. Endocervix shows focal atypical glands suspicious for adenocarcinoma in situ. The margins are negative for tumor. Bilateral fallopian tubes and ovaries are unremarkable. HOLDOVER to evaluate on permanent sections. See comment.

B. Lymph nodes, right pelvic, excision: Multiple (19) lymph nodes are negative for tumor.

C. Lymph nodes, left pelvic, excision: Multiple (15) lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

D. Lymph nodes, left para-aortic, excision: Multiple (14) lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

E. Lymph nodes, right para-aortic, excision: Multiple (2) lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

Frozen section histologic interpretation performed by:

Comment: Permanent sections revealed severe atypia in fallopian tubes.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, left and right fallopian tube and ovary" is a 195.0 gram disrupted uterus with attached bilateral tubes and ovaries. The cervix is nearly detached, 4.5 cm from the ectocervical margin. Multiple portions of a polypoid exophytic mass measuring 6.5 x 6.4 x 5.0 cm in aggregate are present, separately. There is a 7.5 x 7.0 x 2.0 cm exophytic/polypoid, friable mass circumferentially involving the endometrial cavity, grossly invading 2.0 cm. The myometrial thickness is 2.4 cm. There are no leiomyomas. There is a 2.1 x 1.2 x 0.5 cm right ovary with a smooth outer surface and a cystic cut surface with a 6.9 x 0.4 cm right fallopian tube which is unremarkable. There is a 1.9 x 1.7 x 1.3 cm left ovary with a smooth surface and a solid cut surface with a 6.8 x 0.4 cm left fallopian tube which is unremarkable. On cut surface, the left ovary contains a 0.7 x 0.7 x 0.6 cm white yellow solid nodule. Representative sections are submitted.

B. Received fresh labeled "right pelvic lymph nodes" is a 4.9 x 4.8 x 1.4 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.

C. Received fresh labeled "left pelvic lymph nodes" is a 4.4 x 3.3 x 1.5 cm aggregate of adipose and lymphatic tissue. Lymph nodes all submitted.

D. Received fresh labeled "left para-aortic lymph nodes" is a 3.2 x 2.2 x 1.4 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.

E. Received fresh labeled "right para-aortic lymph nodes" is a 1.9 x 0.5 x 0.5 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.

Qual/Synchronous Summary Noted		

Source: NCI Genomic Data Commons file 5a0c5fbc-5b31-42f9-8026-c3de9fca3a48 (TCGA-NF-A4X2.7FC4954E-727C-40F0-8EAF-5C405E7F6B37.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).